Somatic mutation profile of tumor specimen TCGA-17-Z005-01A (aliquot TCGA-17-Z005-01A-01W-0746-08) from TCGA case TCGA-17-Z005, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99cfabdf-62e3-484e-8d01-5af18b1663b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z005-11A (Solid Tissue Normal), aliquot TCGA-17-Z005-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/daa62b29-d8fe-43eb-bb9c-669eaec73123

The open-access MAF lists 95 somatic variants for this specimen: 66 protein-altering or splice-affecting, 29 silent.
By variant classification: Missense Mutation 56, Silent 29, Nonsense Mutation 4, Frame Shift Del 3, Nonstop Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 18/90 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C12orf42 | c.31del p.E11Kfs*6 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as COSV59381039; called by mutect2, pindel, varscan2
- CD3D | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1171878788; called by muse, mutect2
- CDH10 | c.1084C>A p.L362I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.736); catalogued as COSV52577406; called by mutect2, varscan2
- CEP164 | c.875G>A p.S292N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.301); catalogued as rs1565510532; called by muse, mutect2
- FAM71C | c.271C>A p.P91T | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs745698238, COSV60943604; called by muse, mutect2, varscan2
- FAT4 | c.13900G>T p.D4634Y | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100628629; called by muse, mutect2, varscan2
- FBLN1 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as rs750475004; called by mutect2, varscan2
- HMCN1 | c.4550G>T p.R1517I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as COSV54944611; called by muse, mutect2, varscan2
- NRG3 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs769873495, COSV64583766; called by muse, mutect2, varscan2
- NRG3 | c.1556C>G p.P519R | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs531162942, COSV100930908; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as rs1187532664; called by muse, mutect2, varscan2
- POU2F1 | c.221C>T p.S74F (on ENST00000541643 / NM_001365848.1; = p.S97F on NM_002697.4) | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs144698259; called by muse, mutect2
- RASD2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99332705; called by muse, mutect2, varscan2
- RECK | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1445197752; called by muse, mutect2, varscan2
- ROR1 | c.2560C>G p.R854G | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.09); catalogued as COSV64294352; called by muse, mutect2
- SLC19A3 | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs1453840554; called by mutect2, varscan2
- SLCO1B1 | c.114T>A p.F38L | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.183); catalogued as COSV99919112; called by muse, mutect2, varscan2
- SP140 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV59451496; called by muse, mutect2, varscan2
- SULF1 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs746268118, COSV52678852, COSV52683316; called by muse, mutect2, varscan2
- TMPRSS2 | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as rs777667088, COSV59822661; called by mutect2, varscan2
- TRIM58 | c.1062A>T p.E354D | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757138461; called by muse, mutect2, varscan2
- TTN | c.53920C>A p.L17974M (on ENST00000591111; = p.L10550M on NM_003319.4) | Missense Mutation (SNP) | VAF 5/98 reads (5%) | PolyPhen possibly damaging (0.549); catalogued as COSV100621966; called by muse, mutect2
- TTN | c.25636T>A p.W8546R (on ENST00000591111; = p.W7619R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | PolyPhen probably damaging (0.999); catalogued as COSV60195421; called by muse, mutect2, varscan2
- XIRP2 | c.2340C>A p.N780K (on ENST00000628543; = p.N955K on NM_152381.6) | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.397); catalogued as rs1352316546; called by muse, mutect2, varscan2
- ZNF470 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1262553277, COSV100401271; called by muse, mutect2, varscan2
- ANKRD26 | c.3782A>T p.K1261M | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- ASIC2 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- B9D1 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- C11orf53 | c.309C>A p.S103R | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CPXM2 | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- EGR1 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERP27 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FAM160A2 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 48/365 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- GOLGA3 | c.3434G>T p.R1145M | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HGSNAT | c.893C>T p.T298I | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- IKZF4 | c.1160del p.P387Hfs*56 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- IL27 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- IRX2 | c.1087A>C p.T363P | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ITGA2 | c.3546A>C p.*1182Cext*21 | Nonstop Mutation (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- ITGB1 | c.2382G>C p.K794N | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KANSL1 | c.2966G>T p.R989M (on ENST00000574590 / NM_001193465.2; = p.R990M on NM_015443.4) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LGR5 | c.65dup p.S23Qfs*95 | Frame Shift Ins (INS) | VAF 8/45 reads (18%) | called by mutect2, pindel, varscan2
- LRIG2 | c.2581A>G p.T861A | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- LRP1B | c.13186G>T p.G4396C | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- LRP1B | c.13185T>A p.D4395E | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0.017); called by muse, varscan2
- LRP5 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAGEB18 | c.95T>A p.V32E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MICAL2 | c.3142G>C p.G1048R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- MOCS3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.315); called by muse, mutect2
- MYH1 | c.3865G>A p.G1289S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- OR11A1 | c.539G>C p.C180S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PIK3C2A | c.1480C>G p.Q494E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2
- PIP4K2A | c.391G>T p.G131* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF19 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- PRUNE2 | c.6541T>G p.S2181A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by mutect2, varscan2
- RBM45 | c.1144A>C p.K382Q (on ENST00000616198 / NM_001365579.1; = p.K380Q on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- RGS6 | c.396C>A p.A132= | Splice Region (SNP) | VAF 12/99 reads (12%) | called by muse, mutect2, varscan2
- RPS6KL1 | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- SP3 | c.1659A>T p.E553D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2
- SPHKAP | c.4861G>T p.D1621Y (on ENST00000392056 / NM_001142644.2; = p.D1592Y on NM_030623.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SYNE1 | c.1587G>T p.K529N (on ENST00000367255 / NM_182961.4; = p.K536N on NM_033071.3) | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TINAG | c.1316del p.G439Efs*16 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- WDFY3 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2
- ZNF287 | c.860T>G p.I287S | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF687 | c.1999A>T p.T667S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCB4 | c.633C>A p.I211= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- AC008676.3 | c.558G>A p.K186= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS14 | c.168G>T p.V56= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- ALOXE3 | c.1581G>T p.V527= | Silent (SNP) | VAF 12/109 reads (11%) | called by mutect2, varscan2
- ARMC3 | c.837C>A p.L279= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99957466; called by muse, mutect2
- BLZF1 | c.6T>C p.T2= | Silent (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- BSN | c.2136G>T p.G712= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- CCDC9B | c.441G>A p.E147= | Silent (SNP) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- CDHR2 | c.3402G>A p.G1134= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- CEACAM7 | c.393G>T p.V131= | Silent (SNP) | VAF 20/111 reads (18%) | catalogued as COSV50073724; called by muse, mutect2
- CHRM2 | c.939C>A p.G313= | Silent (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- CST9 | c.292C>T p.L98= | Silent (SNP) | VAF 19/117 reads (16%) | called by muse, mutect2, varscan2
- CYP2E1 | c.741T>C p.S247= | Silent (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- DDI1 | c.453C>A p.L151= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs1262172456; called by muse, mutect2, varscan2
- ELAC1 | c.774G>C p.V258= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- FLG | c.3627G>T p.G1209= | Silent (SNP) | VAF 38/266 reads (14%) | called by muse, mutect2, varscan2
- GOPC | c.1317T>C p.S439= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs772993216; called by muse, mutect2, varscan2
- IRAG1 | c.756C>A p.V252= | Silent (SNP) | VAF 4/41 reads (10%) | called by muse, varscan2
- KCND3 | c.324C>T p.Y108= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs777559132; called by muse, mutect2, varscan2
- LBR | c.1320G>T p.A440= | Silent (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- MXRA5 | c.8154C>A p.G2718= | Silent (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- OPA3 | c.528G>A p.A176= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs752240099, COSV54399142; called by muse, mutect2, varscan2
- ROBO2 | c.2235A>C p.V745= | Silent (SNP) | VAF 26/76 reads (34%) | called by muse, mutect2, varscan2
- S100A7L2 | c.36C>T p.D12= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, varscan2
- SOBP | c.1674C>T p.N558= | Silent (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- SYT13 | c.1062C>A p.P354= | Silent (SNP) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- TPD52L3 | c.135C>G p.T45= | Silent (SNP) | VAF 21/79 reads (27%) | called by muse, mutect2, varscan2
- ZFHX4 | c.8394C>A p.T2798= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- ZNF423 | c.837C>A p.T279= (on ENST00000563137 / NM_001379286.1; = p.T271= on NM_015069.4) | Silent (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
